Somatic mutation profile of tumor specimen TCGA-G4-6303-01A (aliquot TCGA-G4-6303-01A-11D-1771-10) from TCGA case TCGA-G4-6303, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 54.2 years (19,800 days).
Specimen TCGA-G4-6303-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dd2cecd-2910-483e-98d3-9d4e127e50c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6303-10A (Blood Derived Normal), aliquot TCGA-G4-6303-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6d6ef80-86bc-4617-b5dc-443272e5543a

The open-access MAF lists 108 somatic variants for this specimen: 73 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 30, Nonsense Mutation 9, Intron 3, Frame Shift Ins 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 112/131 reads (85%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NDUFS1 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | catalogued as rs372691318, CM012412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 66/92 reads (72%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1380263448, COSV56980181, COSV56991886; called by muse, mutect2, varscan2
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2, varscan2
- ANKRD30A | c.993G>T p.L331F (on ENST00000611781; = p.L275F on NM_052997.2) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV64617046; called by muse, mutect2, varscan2
- ANKRD30A | c.1945C>A p.Q649K (on ENST00000611781; = p.Q593K on NM_052997.2) | Missense Mutation (SNP) | VAF 86/528 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1230786574, COSV100654518; called by muse, mutect2, varscan2
- AP5S1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs994202221, COSV55694471; called by muse, mutect2, varscan2
- ARAP1 | c.3479G>A p.R1160H (on ENST00000393609 / NM_001040118.2; = p.R915H on NM_015242.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs781671391, COSV100501493, COSV61993603; called by muse, mutect2, varscan2
- BOD1L1 | c.3056G>T p.G1019V | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50037851; called by muse, mutect2, varscan2
- BSN | c.8876G>A p.R2959H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748163157, COSV56524463; called by muse, mutect2, varscan2
- CD40 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 54/572 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs1309660087, COSV64848133; called by muse, mutect2
- CDH12 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 12/256 reads (5%) | catalogued as COSV66389392; called by muse, mutect2
- CENPF | c.1128A>C p.Q376H | Missense Mutation (SNP) | VAF 97/483 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV65277589; called by muse, mutect2, varscan2
- CENPJ | c.2305A>C p.I769L | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67883961; called by muse, mutect2, varscan2
- CFAP45 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 297/489 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774486512, COSV63650344; called by muse, mutect2, varscan2
- CHPF | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV99705354; called by mutect2, varscan2
- COL24A1 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs774016057, COSV65305622; called by muse, mutect2, varscan2
- CYP1B1 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 23/121 reads (19%) | catalogued as rs1240682197, COSV52228080; called by muse, mutect2, varscan2
- DBH | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as rs148244950; called by muse, mutect2, varscan2
- DYNC2H1 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as rs765037166, COSV62102286; called by muse, mutect2, varscan2
- EFCAB6 | c.3619C>T p.R1207C | Missense Mutation (SNP) | VAF 99/200 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs367565154, COSV53069025; called by muse, mutect2, varscan2
- EPHB1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 57/150 reads (38%) | catalogued as COSV67661962, COSV67663055; called by muse, mutect2, varscan2
- ESYT3 | c.62C>A p.P21Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV56681354; called by muse, mutect2, varscan2
- EXOC8 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50479152; called by muse, mutect2, varscan2
- FAM47A | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.073); catalogued as rs1339397781, COSV60497528; called by muse, mutect2, varscan2
- GPR135 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs776476442, COSV67749758; called by muse, mutect2, varscan2
- GPR179 | c.2474C>T p.T825M (on ENST00000621958; = p.T824M on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as rs757140865; called by muse, mutect2, varscan2
- GSDMD | c.1452C>G p.H484Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV52797976; called by muse, mutect2, varscan2
- HTRA3 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56472428; called by muse, mutect2, varscan2
- JARID2 | c.1786C>T p.R596W | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs781217563, COSV59194984; called by muse, mutect2, varscan2
- KLHL5 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 311/407 reads (76%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1336800740, COSV54676855; called by muse, mutect2, varscan2
- MCCC2 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 126/432 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs772144978, COSV60156194; called by muse, mutect2, varscan2
- MROH9 | c.247A>T p.K83* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as COSV63013364; called by muse, mutect2, varscan2
- MRPS11 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as COSV100363821, COSV57915107; called by muse, mutect2, varscan2
- MSN | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64303274, COSV64305045; called by muse, mutect2, varscan2
- MTUS2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 156/214 reads (73%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs558234447, COSV70919441; called by muse, mutect2, varscan2
- NCOA2 | c.37A>T p.R13W | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV71764607; called by muse, mutect2, varscan2
- NOP58 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 53/117 reads (45%) | catalogued as COSV51898031; called by muse, mutect2, varscan2
- OR4K17 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 114/152 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59648794; called by muse, mutect2, varscan2
- OR9A4 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs540557231, COSV71885855; called by muse, mutect2, varscan2
- OSCP1 | c.505C>T p.R169W (on ENST00000356637 / NM_001330493.1; = p.R159W on NM_145047.5) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569111580, COSV52487633; called by muse, mutect2, varscan2
- PACRG | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775007947, COSV61309987; called by muse, mutect2, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 226/369 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PCDHB4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs1425672587, COSV52024729; called by muse, mutect2, varscan2
- PDE10A | c.97C>A p.L33I | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs185608480, COSV63103002; called by muse, mutect2, varscan2
- PERP | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs774124818, COSV69827681; called by muse, mutect2, varscan2
- PIK3R3 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs80189271, COSV53110088; called by muse, mutect2, varscan2
- PLOD1 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV99539100; called by muse, mutect2
- RGS6 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 96/179 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs149826345, COSV59600557; called by muse, mutect2, varscan2
- SAGE1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 111/694 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs181135819, COSV61012942, COSV61016070; called by muse, mutect2, varscan2
- SASS6 | c.1869C>T p.D623= | Splice Region (SNP) | VAF 20/63 reads (32%) | catalogued as COSV54927996, COSV54929509; called by muse, mutect2, varscan2
- SCN1A | c.4096G>A p.V1366I (on ENST00000303395 / NM_001202435.3; = p.V1355I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918805, CM076498, COSV57681267; ClinVar: not provided; called by muse, mutect2, varscan2
- SCN5A | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs759584454, COSV61135533, COSV99048706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC35A5 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53727642; called by muse, mutect2, varscan2
- SLC6A2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs760211721, COSV54920970; called by muse, mutect2, varscan2
- SMAD9 | c.1192G>C p.V398L (on ENST00000379826 / NM_001127217.3; = p.V361L on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1490771687, COSV100615068; called by muse, mutect2, varscan2
- SMU1 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV68140099; called by muse, mutect2, varscan2
- SNED1 | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs376117940, COSV100122528; called by muse, mutect2, varscan2
- STOML2 | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53054717; called by muse, mutect2, varscan2
- SYNDIG1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as rs373605642; called by muse, mutect2, varscan2
- THBS2 | c.1013G>T p.C338F | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64681237; called by muse, mutect2, varscan2
- TMEM131L | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 117/520 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1287688992, COSV53644662; called by muse, mutect2, varscan2
- TMEM181 | c.1357C>A p.L453I | Missense Mutation (SNP) | VAF 22/361 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.518); catalogued as COSV100892679; called by muse, mutect2
- TSPO2 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV55111254, COSV99770900; called by muse, mutect2, varscan2
- VWA7 | c.2471G>A p.R824Q | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs763158449, COSV65173921; called by muse, mutect2, varscan2
- WDR26 | c.2005C>T p.Q669* (on ENST00000414423 / NM_001379403.1; = p.Q569* on NM_025160.7) | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as COSV54358596; called by muse, mutect2, varscan2
- WHRN | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1413225135, COSV54333597; called by muse, mutect2, varscan2
- ZMYM3 | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs766683638, COSV58739848; called by muse, mutect2, varscan2
- ZNF518A | c.3926G>A p.R1309H | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs368890631; called by muse, mutect2, varscan2
- ZNF540 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV57110811; called by muse, mutect2, varscan2
- OR8H1 | c.185dup p.L63Pfs*8 | Frame Shift Ins (INS) | VAF 39/230 reads (17%) | called by mutect2, pindel, varscan2
- ZBBX | c.2109dup p.E704Rfs*42 | Frame Shift Ins (INS) | VAF 50/299 reads (17%) | called by mutect2, pindel, varscan2
- BRIP1 | c.2058T>G p.T686= | Silent (SNP) | VAF 104/244 reads (43%) | catalogued as COSV52005618; called by muse, mutect2, varscan2
- C3 | c.2982C>T p.A994= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs1211919460, COSV55578459; called by muse, mutect2, varscan2
- CDH24 | c.873C>T p.N291= | Silent (SNP) | VAF 41/52 reads (79%) | catalogued as rs369160830, COSV99399437; called by muse, mutect2, varscan2
- CYP11B2 | c.1230G>A p.L410= | Silent (SNP) | VAF 128/188 reads (68%) | catalogued as COSV59997247; called by muse, mutect2, varscan2
- DGKH | c.441G>A p.E147= | Silent (SNP) | VAF 103/389 reads (26%) | catalogued as rs779557188, COSV99819672; called by muse, varscan2
- DMBT1 | c.2232C>T p.G744= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs778751058, COSV57553873; called by muse, mutect2, varscan2
- DNAH3 | c.2802C>T p.I934= | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as rs963838132, COSV54540609; called by muse, mutect2, varscan2
- FBXL7 | c.1269G>A p.L423= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV100310734, COSV61650386; called by muse, mutect2, varscan2
- GJA8 | c.384C>T p.S128= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV53790006; called by muse, mutect2, varscan2
- GPC4 | c.1218C>T p.N406= | Silent (SNP) | VAF 12/328 reads (4%) | catalogued as COSV100895612; called by muse, mutect2
- H4C2 | c.219C>T p.Y73= | Silent (SNP) | VAF 94/151 reads (62%) | catalogued as rs769477226, COSV55140085; called by muse, mutect2, varscan2
- HYOU1 | c.2991C>T p.D997= | Silent (SNP) | VAF 65/399 reads (16%) | catalogued as rs573944250, COSV68216917; called by muse, mutect2, varscan2
- IL31 | c.213G>A p.P71= | Silent (SNP) | VAF 80/316 reads (25%) | catalogued as rs376559865; called by muse, mutect2, varscan2
- ITIH5 | c.645C>T p.R215= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV56911180; called by muse, mutect2, varscan2
- KCNH4 | c.2856G>A p.T952= | Silent (SNP) | VAF 33/229 reads (14%) | catalogued as rs781508246, COSV52916278; called by muse, mutect2, varscan2
- LRP1B | c.12987T>C p.C4329= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV101261650; called by muse, mutect2
- LRRTM4 | c.1729A>C p.R577= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV69165305, COSV69171164; called by muse, mutect2, varscan2
- MAP2 | c.3861C>T p.I1287= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs772176261, COSV52302492; called by muse, mutect2, varscan2
- MELK | c.1143A>G p.L381= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs762432984, COSV53201148; called by muse, mutect2, varscan2
- PCDHGB2 | c.1827G>T p.L609= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- POU3F1 | c.867G>A p.S289= | Silent (SNP) | VAF 11/166 reads (7%) | catalogued as COSV100884730; called by muse, mutect2
- PRB2 | c.987C>T p.P329= | Silent (SNP) | VAF 24/382 reads (6%) | catalogued as COSV66982812, COSV66982907; called by muse, mutect2
- PRKDC | c.1896G>A p.E632= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs774814292, COSV58059928; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A36 | c.798G>A p.Q266= (on ENST00000324194 / NM_001104647.3; = p.Q265= on NM_018155.3) | Silent (SNP) | VAF 61/162 reads (38%) | catalogued as COSV60782810; called by muse, mutect2, varscan2
- SLC7A1 | c.1131C>T p.N377= | Silent (SNP) | VAF 140/506 reads (28%) | catalogued as rs574126039, COSV66331071; called by muse, mutect2, varscan2
- SPIN4 | c.141C>T p.H47= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV58738374; called by muse, mutect2, varscan2
- TFF2 | c.105C>T p.S35= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1270153960, COSV52296993; called by muse, mutect2, varscan2
- TMPRSS12 | c.261C>T p.G87= | Silent (SNP) | VAF 65/134 reads (49%) | catalogued as rs1309304663, COSV68256945; called by muse, mutect2, varscan2
- USP42 | c.951G>T p.L317= | Silent (SNP) | VAF 61/296 reads (21%) | catalogued as COSV60363210; called by muse, mutect2, varscan2
- WNT7B | c.504C>T p.D168= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs932330177, COSV59751629; called by muse, mutect2, varscan2
- MIR424 | n.77G>A | RNA (SNP) | VAF 50/207 reads (24%) | called by muse, mutect2, varscan2
- OFCC1 | n.393-2948C>T | Intron (SNP) | VAF 81/163 reads (50%) | catalogued as rs374888926; called by muse, mutect2, varscan2
- PARGP1 | n.1863C>T | RNA (SNP) | VAF 123/504 reads (24%) | catalogued as rs1232344651; called by muse, mutect2, varscan2
- PTPRT | c.2176+12050G>A | Intron (SNP) | VAF 172/224 reads (77%) | catalogued as rs951719751, COSV62005984; called by muse, mutect2, varscan2
- SYTL2 | c.1459+2853G>C | Intron (SNP) | VAF 50/118 reads (42%) | catalogued as COSV60361888; called by muse, mutect2, varscan2
